CCDI case PBBYVY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/99129b31-d0f2-47d4-b2c8-6367a70f3d7a

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Desmoplastic nodular medulloblastoma: ICD-O-3 morphology code: 9471/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.5 years (534 days).

Biospecimens (3 samples)
- Sample 0DKWN4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKWNB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DKWNR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
